Gene-level copy-number profile of tumor specimen TCGA-CG-4443-01A from TCGA case TCGA-CG-4443, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 68.4 years (24,990 days).
Specimen TCGA-CG-4443-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.9684f7fa-5cdc-4976-9833-c4d95a8f86e6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-4443-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4dca9a2b-fda4-4bc4-aa6c-4817d15f5dcf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 15,986; copy number 2: 37,886; copy number 3: 4,076; copy number 4: 992; copy number 5: 287; copy number 6: 87; copy number 7: 424; copy number 8: 45.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CG-4443-01A-01D-1155-01): tumor purity 0.87, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,094,161–88,259,372, 31 genes: SHLD2, AL136982.3, RN7SL733P, NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A, LINC00863, NUTM2D, NPAP1P3, CTSLP1, FAM245A, AL355334.1, AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 843 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:83,912,713–85,540,511, 24 genes, copy number 5–6 (within-gene range 5–7): AC015522.1, TPM3P3, AC012400.1, RALYL, RNU6-1040P, PSMC2P2, AC009901.1, AC009901.2, ACTBP6, JCHAINP1, AC091175.1, LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2, CA1, CA3, CA3-AS1, CA2, AC084734.1.
- chr8:89,243,401–90,053,633, 10 genes, copy number 7 (within-gene range 4–7): RPSAP74, KRT8P4, AF117829.1, RIPK2, COX6B1P6, AF117829.2, RNU6-925P, OSGIN2, NBN, DECR1.
- chr13:72,453,902–73,995,056, 25 genes, copy number 6 (within-gene range 3–6): AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1.
- chr13:84,086,802–86,170,890, 14 genes, copy number 5 (within-gene range 3–5): AL162493.1, MTND4P1, MTND5P3, LINC00333, AL445588.1, AL356313.1, LINC00375, AL160154.1, LINC00351, AL356413.1, SLITRK6, AL162373.1, MOB1AP1, AL354994.1.
- chr17:78,674,048–83,095,122, 204 genes, copy number 5–6 (broad region; genes not listed).
- chr20:42,968,743–64,313,132, 566 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,750. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
